Gene-level copy-number profile of tumor specimen HTMCP-03-06-02202-01B from CGCI case HTMCP-03-06-02202, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIB; Tumor grade: G2.
Specimen HTMCP-03-06-02202-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file fcd2c24e-f3f5-4ad9-a112-5e5e448c0e15.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02202-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,236 have no estimate.
https://portal.gdc.cancer.gov/files/c8804c64-f2c3-45dc-be34-36b1a81384a5

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 3; copy number 2: 113; copy number 3: 6,267; copy number 4: 27,309; copy number 5: 9,754; copy number 6: 8,765; copy number 7: 1,193; copy number 8: 2,128; copy number 9: 2,325; copy number 11: 407; copy number 12: 59; copy number 13: 7; copy number 18: 2.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:32,008,438–32,188,107, 9 genes (within-gene range 0–2): AC142381.4, IGHV1OR16-1, AC142381.1, IGHV1OR16-3, IGHV3OR16-9, HERC2P4, AC142381.2, AC133485.7, AC133485.6.
- chr16:32,213,380–32,380,049, 8 genes: AC133485.1, AC133485.3, TP53TG3D, AC133485.2, AC140878.1, AC133548.2, AC133548.1, ACTR3BP3.
- chr16:32,869,985–32,873,128, 1 gene: BCAP31P2.
- chr16:33,533,816–33,554,408, 3 genes: AC136944.1, AC136944.2, AC136944.4.
- chr16:33,808,778–33,810,767, 1 gene: AC136428.3.
- chr20:14,933,843–15,022,958, 3 genes (within-gene range 0–8): AL138808.1, RNU6-1159P, RNU6-115P.
- chr21:7,744,962–8,680,934, 28 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1, RPSAP68, CR381572.2.
- chr21:13,095,305–13,120,807, 2 genes: ZNF355P, AJ239321.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 791 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:21,997,539–22,482,959, 37 genes, copy number 9 (within-gene range 6–9): TRAV17, TRAV18, TRAV19, AC245505.2, TRAV20, TRAV21, AC245505.3, TRAV22, TRAV23DV6, TRDV1, TRAV24, TRAV25, TRAV26-1, TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, AC244502.1, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2.
- chr14:22,462,932–22,482,346, 10 genes, copy number 9 (within-gene range 6–9): TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 9: TRAC.
- chr14:99,158,416–99,332,015, 4 genes, copy number 13: AL162151.1, BCL11B, AL109767.1, AL132819.1.
- chr14:106,850,885–106,879,812, 6 genes, copy number 9: MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr16:33,562,649–33,570,935, 1 gene, copy number 9: AC136944.3.
- chr16:33,964,547–34,051,363, 7 genes, copy number 9–18: AC140658.1, AC140658.5, AC133561.1, BCAP31P1, AC133561.2, AC133561.4, AC133561.3.
- chr16:34,135,736–34,163,110, 6 genes, copy number 12: DUX4L45, PCMTD1P2, DUX4L46, DUX4L47, LINC00273, RNA5-8SP2.
- chr19:44,631,573–44,725,217, 2 genes, copy number 9 (within-gene range 8–9): AC243964.3, PVR.
- chr19:44,662,278–49,275,420, 260 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr20:18,383,367–20,972,562, 45 genes, copy number 11: DZANK1, GCNT1P1, RNA5SP476, POLR3F, MIR3192, RPL21P3, RBBP9, RPS19P1, SEC23B, SMIM26, AL121900.1, DTD1, RN7SL638P, RNU6ATAC34P, DUXAP7, DTD1-AS1, EEF1A1P34, LINC00652, LINC00653, SCP2D1-AS1, SCP2D1, AL135936.1, SLC24A3, AL136090.1, SLC24A3-AS1, AL121830.1, AL121761.1, RIN2, RPL12P12, NAA20, CRNKL1, CFAP61, AL035454.1, AL049648.1, RPL17P1, CFAP61-AS1, RN7SL690P, AL161658.1, INSM1, RALGAPA2, EIF4E2P1, LLPHP1, RN7SL607P, MRPS11P1, AL133465.1.
- chr20:24,679,547–25,752,776, 33 genes, copy number 11: AL049594.1, AL035661.1, CST7, APMAP, RNU6-1257P, AL035661.2, ACSS1, AL080312.2, VSX1, AL080312.1, AL035252.2, AL035252.1, ENTPD6, Y_RNA, AL035252.4, AL035252.3, AL121772.1, PYGB, AL121772.2, AL121772.3, ABHD12, PPIAP2, GINS1, NINL, RNU6ATAC17P, NANP, ZNF337-AS1, RN7SL594P, MED28P7, ZNF337, AL031673.1, AL390198.1, VN1R108P.
- chr20:32,858,923–34,123,290, 41 genes, copy number 11: EFCAB8, SUN5, BPIFB2, BPIFB6, PUDPP3, BPIFB3, BPIFB4, BPIFA2, SOCS2P1, BPIFA4P, AL121901.1, BPIFA3, BPIFA1, RPL12P3, BPIFB1, BPIFB5P, BPIFB9P, CDK5RAP1, SNTA1, CBFA2T2, AL121906.2, NECAB3, C20orf144, ACTL10, ACTL10, AL121906.1, E2F1, PXMP4, AL050349.1, ZNF341, RPL31P2, ZNF341-AS1, CHMP4B, TPM3P2, PIGPP3, RALY-AS1, RALY, AL031668.1, MIR4755, EIF2S2, RPS2P1.
- chr20:37,101,226–37,975,481, 18 genes, copy number 11: MROH8, AL031659.1, RPN2, GHRH, MANBAL, SRC, RPL7AP14, BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185.
- chr20:43,388,642–53,495,330, 266 genes, copy number 9–11 (within-gene range 8–11) (broad region; genes not listed).
- chr20:63,343,223–64,079,988, 53 genes, copy number 12: CHRNA4, AL121827.1, KCNQ2, AL353658.1, KCNQ2-AS1, EEF1A2, AL121829.1, PPDPF, PTK6, SRMS, AL121829.2, FNDC11, HELZ2, GMEB2, MHENCR, STMN3, RTEL1, RTEL1-TNFRSF6B, TNFRSF6B, ARFRP1, ZGPAT, AL121845.3, AL121845.4, LIME1, AL121845.2, SLC2A4RG, ZBTB46, AL121845.1, ZBTB46-AS1, C20orf181, AL118506.1, ABHD16B, TPD52L2, DNAJC5, RNU1-134P, MIR941-1, MIR941-2, MIR941-3, MIR941-4, MIR941-5, UCKL1, MIR1914, MIR647, UCKL1-AS1, ZNF512B, SAMD10, PRPF6, C20orf204, SOX18, TCEA2, AL355803.1, RGS19, MIR6813.
- chr21:12,999,676–13,016,692, 1 gene, copy number 9: AP001464.1.

Autosomal genes at a single copy (total copy number 1): 3. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
